Somatic mutation profile of tumor specimen 1f5a9aad-61a1-4a64-a9b0-38cd2b (aliquot 1f5a9aad-61a1-4a64-a9b0-38cd2b_D6_2) from CPTAC case 01BR030, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 83.9 years (30,659 days).
Specimen 1f5a9aad-61a1-4a64-a9b0-38cd2b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) add54a9e-ae92-4373-ab6a-e0bf874581f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a2b1c102-3c96-4e75-bd12-e6b33f (Blood Derived Normal), aliquot a2b1c102-3c96-4e75-bd12-e6b33f_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d62ea21c-d018-4330-b54b-f7125043fd6f

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Ins 2, Intron 2, 5'UTR 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.4414C>T p.R1472W | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60104289; called by muse, mutect2
- ARID1A | c.2105dup p.P703Sfs*114 | Frame Shift Ins (INS) | VAF 43/257 reads (17%) | catalogued as COSV61385117; called by mutect2, pindel, varscan2
- ATXN1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 113/505 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773627110, COSV55216808; called by muse, mutect2, varscan2
- CATSPER1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 46/467 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs370786090; called by muse, mutect2, varscan2
- CEP104 | c.2377T>C p.S793P | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs745318217; called by muse, mutect2, varscan2
- CNKSR2 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1413945141; called by muse, mutect2, varscan2
- CPT1C | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs756410814, COSV54919597, COSV54922054; called by muse, mutect2, varscan2
- DNHD1 | c.10024C>T p.R3342W | Missense Mutation (SNP) | VAF 43/534 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769777880; called by muse, mutect2
- KLHL34 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1432124735; called by muse, mutect2, varscan2
- LRRK1 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs530260600, COSV52613186; called by muse, mutect2, varscan2
- PNPLA3 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs201295166, COSV53381169; called by muse, mutect2, varscan2
- RYR2 | c.13490G>A p.R4497H | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867681818, COSV63677657; called by muse, mutect2
- TRANK1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs777398563, COSV57140943; called by muse, mutect2, varscan2
- TTC28 | c.5132T>A p.I1711N | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67417727; called by muse, mutect2, varscan2
- AFF4 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COG1 | c.1904A>G p.K635R | Missense Mutation (SNP) | VAF 46/704 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2
- GABRB1 | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GATA3 | c.962dup p.T322Dfs*30 | Frame Shift Ins (INS) | VAF 34/311 reads (11%) | called by mutect2, pindel, varscan2
- GHSR | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 20/568 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- INSR | c.3398T>C p.L1133P | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MYBBP1A | c.3105G>T p.Q1035H | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- N4BP2 | c.1062G>T p.L354F | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2
- PCDH9 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDXDC1 | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC61B | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMC3 | c.1088G>T p.S363I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TRAFD1 | c.365A>T p.N122I | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- URI1 | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VIPAS39 | c.1115C>G p.T372R | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WDR7 | c.1058T>G p.L353W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZFPM2 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 47/541 reads (9%) | called by muse, mutect2
- ZNF85 | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF91 | c.2553G>C p.E851D | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- ADAM19 | c.999C>T p.S333= | Silent (SNP) | VAF 55/252 reads (22%) | catalogued as rs377513607; called by muse, mutect2, varscan2
- DOCK8 | c.3480C>T p.T1160= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as rs764046452; called by muse, mutect2, varscan2
- GLI1 | c.438G>A p.S146= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs148571068, COSV57359570; called by muse, mutect2, varscan2
- INSL3 | c.132C>T p.R44= | Silent (SNP) | VAF 38/224 reads (17%) | catalogued as rs756992784; called by muse, mutect2
- MUC17 | c.954G>A p.T318= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as rs775661782, COSV60285545; called by muse, mutect2, varscan2
- MZF1 | c.849C>T p.L283= | Silent (SNP) | VAF 70/236 reads (30%) | catalogued as rs1261977105; called by muse, mutect2, varscan2
- NBPF4 | c.1869C>T p.S623= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs2582071; called by muse, mutect2
- RPTOR | c.3498C>T p.D1166= | Silent (SNP) | VAF 34/310 reads (11%) | called by muse, mutect2
- SLC1A6 | c.39C>T p.S13= | Silent (SNP) | VAF 14/159 reads (9%) | catalogued as rs772018990, COSV55671337; called by muse, mutect2
- SLC9A4 | c.441C>T p.P147= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- ADGRG1 | c.-6A>C | 5'UTR (SNP) | VAF 97/409 reads (24%) | called by muse, mutect2, varscan2
- C12orf76 | n.664+6117G>A | Intron (SNP) | VAF 114/372 reads (31%) | catalogued as rs1184404544; called by muse, varscan2
- LITAF | chr16:11547815 A>G | 3'Flank (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- TAF1D | c.-107A>T | 5'UTR (SNP) | VAF 26/170 reads (15%) | called by mutect2, varscan2
- UBXN7 | c.73+54G>C | Intron (SNP) | VAF 38/167 reads (23%) | called by muse, mutect2, varscan2
